Somatic mutation profile of tumor specimen C3L-02955-01 (aliquot CPT0196850009) from CPTAC case C3L-02955, project CPTAC-3 (Brain — Gliomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 76.3 years (27,855 days).
Specimen C3L-02955-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a62e5cf9-5db9-4529-9035-86fee345f58d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02955-31 (Blood Derived Normal), aliquot CPT0197750002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5739b9cb-b29e-4c3b-b6a1-051658496285

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Nonsense Mutation 3, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2251G>C p.G751R | Missense Mutation (SNP) | VAF 17/180 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1567847681, CS076636, COSV100648504, COSV62198240, COSV62228997; ClinVar: likely pathogenic; called by muse, mutect2
- CDH15 | c.1088G>A p.R363H | Missense Mutation (SNP) | VAF 31/654 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs750887359; called by muse, mutect2
- LMTK2 | c.2646G>T p.R882S | Missense Mutation (SNP) | VAF 17/274 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1323329049; called by muse, mutect2
- OR5T3 | c.388A>G p.M130V | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.468); catalogued as rs1565089075; called by muse, mutect2
- PLA2G10 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1315484389; called by muse, mutect2, varscan2
- TRAPPC9 | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 34/756 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs777722019; called by muse, mutect2
- VMA21 | c.272G>A p.G91D | Missense Mutation (SNP) | VAF 16/278 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as CS092163; called by muse, mutect2
- WDR54 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 23/308 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs375496069; called by muse, mutect2
- ADAMTS5 | c.395A>T p.Y132F | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.148); called by muse, mutect2
- ARHGEF11 | c.1433C>T p.T478I | Missense Mutation (SNP) | VAF 7/148 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.777); called by muse, mutect2
- ATAD1 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 14/142 reads (10%) | called by muse, mutect2
- DMD | c.6470C>G p.T2157S | Missense Mutation (SNP) | VAF 14/289 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2
- KCNV1 | c.758T>C p.F253S | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- KRT39 | c.1371A>G p.I457M | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); called by muse, mutect2
- MTMR1 | c.1376A>G p.Y459C | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- NFKBIZ | c.1591-1G>A p.X531_splice | Splice Site (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- NOMO2 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 13/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); called by muse, mutect2
- NPAS3 | c.1743G>C p.K581N (on ENST00000356141 / NM_001164749.2; = p.K549N on NM_022123.3) | Missense Mutation (SNP) | VAF 26/559 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2
- PDE1A | c.1539G>C p.E513D | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2
- RIOK3 | c.577G>T p.G193* | Nonsense Mutation (SNP) | VAF 6/72 reads (8%) | called by muse, mutect2
- WDR92 | c.789G>A p.W263* | Nonsense Mutation (SNP) | VAF 13/258 reads (5%) | called by muse, mutect2
- ZNF729 | c.1589C>A p.T530N | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.012); called by muse, mutect2
- AHNAK2 | c.8175C>T p.A2725= | Silent (SNP) | VAF 38/612 reads (6%) | catalogued as rs375170748; called by muse, mutect2
- GABRB2 | c.1104T>C p.N368= | Silent (SNP) | VAF 5/74 reads (7%) | called by muse, mutect2
- LDHA | c.714T>C p.A238= | Silent (SNP) | VAF 23/312 reads (7%) | called by muse, mutect2
- MAGEC2 | c.318T>A p.S106= | Silent (SNP) | VAF 9/174 reads (5%) | called by muse, mutect2
- HR | c.*23C>T | 3'UTR (SNP) | VAF 16/264 reads (6%) | catalogued as rs372246310; called by muse, mutect2
